CCDI case PBCHPP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/41bd81d2-c489-4cad-99e8-633bf6e9c169

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.3 years (3,414 days).

Biospecimens (2 samples)
- Sample 0DSCOU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DSCP4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
